Surgical pathology report (de-identified scan), TCGA case TCGA-19-A60I, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-A60I-01A (Primary Tumor).

[page 1 of 3]
M

ICD-O-3

Glioblastoma, multiforme
09440/3
Site Brain NOS C71.9
path @ Brain, frontal lobe C71.1
09441/3

Surgical Pathology Report

--- Clinical History ---

Brain mass [348.9]. Medical History: Brain mass. Mild vitamin D deficiency. Seizures.

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

ontal tumor, left, biopsy:
Glioblastoma, WHO grade IV (see COMMENT).

Frontal tumor #2, left, biopsy:
Glioblastoma, WHO grade IV (see COMMENT).

Frontal tumor, left, excision:
Glioblastoma, WHO grade IV (see COMMENT).

---Comment---

There is marked pleomorphism, numerous atypical mitoses, vascular proliferation, necrosis, and infiltration into the brain matter. These findings are diagnostic of glioblastoma, WHO grade IV. Immunohistochemical stains for p53 and Ki-67 were performed and reviewed. Immunostain for p53 showed weak expression in approximately 10-20% of the tumor cells. The Ki-67 labeling index is estimated at 40%.

All controls show appropriate reactivity.

[page 2 of 3]
M.

The immunohistochemical (IHC) test for HER2/neu and the in-situ hybridization tests were developed by and are performed

All other IHC and histochemical tests were developed by and are performed

All tests reported here, except those addressing HER2/neu overexpression as a predictive marker, are not required to have nor do they have FDA approval.

---Addendum Report---

Addendum

Status: Signed Out

The Ki-67 stain was performed by manual immunohistochemistry.

All controls show appropriate reactivity.

The immunohistochemical (IHC) test for HER2/neu and the in-situ hybridization tests were developed by and are performed

All other IHC and histochemical tests were developed by and are performed

All tests reported here, except those addressing HER2/neu overexpression as a predictive marker, are not required to have nor do they have FDA approval.

---INTRAOPERATIVE CONSULTATION DIAGNOSIS---

AF1. Left frontal tumor (Frozen section performed):
Glioblastoma, WHO IV.

[page 3 of 3]
---SPECIMEN(S) RECEIVED:---

M

A: Neuropath, Brain, Bx
B: Neuropath, Brain, Bx
C: Neuropath, Brain, Bx

---GROSS DESCRIPTION:---

The specimens are received in three properly labeled containers with the patient's name and accession number, one of which was submitted for frozen section.

A. The specimen is designated "left frontal tumor" and consists of a 0.4 x 0.3 x 0.2 cm tan-white fragment of tissue. A touch prep is prepared and a portion of tissue submitted for frozen sectioning, cassette AF1. The remainder of the specimen is entirely submitted in cassette A1.

B. The specimen is designated "left frontal tumor #2" and consists of a 0.8 x 0.5 cm fragment of tan and brown tissue which is trisected and submitted in cassettes B1 through B3.

C. The specimen is designated "left frontal tumor" and consists of a 3.0 x 2.1 x 1.1 cm aggregate of pink and red friable, fragmented irregular portions of soft tissue. This was entirely submitted in cassettes C1 through C4.

Source: NCI Genomic Data Commons file 43df2295-9a3f-4d0a-80b0-2f76a4e28c80 (TCGA-19-A60I.4E59C6BF-3B94-43C4-8269-1C0F271ACB7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).